CCDI case PBCJIV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2e997822-8810-403c-a2f9-5549fbf1844d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,036 days).

Biospecimens (3 samples)
- Sample 0DU7ZN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU81D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DU9N9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
